Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3872, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3872-01A (Primary Tumor).

Diagnosis

Resected colon material with an ulcerated, slightly differentiated adenocarcinoma of the colorectal type, located 3 cm from a resection margin, with infiltration of the pericolic fatty tissue, circumscribed penetration of the covering serosa as well as 23 local lymph node metastases. Partly angioinvasive tumor branches, extending up to the mesenteric resection margin. Tumor-free colon resection margins.

Tumor classification: pT4, pN2 (23/29), pMX; G3, L1, V1, R1.

Source: NCI Genomic Data Commons file 7202b0c4-682f-4d24-a7dd-9b6315abb454 (TCGA-AA-3872.EC2BB4CE-7F58-419E-935F-C6DEED68E68C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).